Somatic mutation profile of tumor specimen TCGA-K4-A3WU-01B (aliquot TCGA-K4-A3WU-01B-11D-A23M-08) from TCGA case TCGA-K4-A3WU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 88.0 years (32,134 days).
Specimen TCGA-K4-A3WU-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e545a2d-3927-4b2b-8b35-c683a9a67cb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A3WU-10A (Blood Derived Normal), aliquot TCGA-K4-A3WU-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbb69469-d8e8-45d2-8a5d-0dd383f36c0b

The open-access MAF lists 194 somatic variants for this specimen: 143 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 47, Nonsense Mutation 5, RNA 2, Frame Shift Ins 2, 5'UTR 1, Splice Site 1, 3'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1637C>T p.S546L (on ENST00000281708 / NM_001349798.2; = p.S466L on NM_018315.5) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55905633, COSV99656643, COSV99660447; called by muse, mutect2, varscan2
- AKAP9 | c.5977G>C p.E1993Q (on ENST00000359028; = p.E1961Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62344059; called by muse, mutect2
- ALAD | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201127458, COSV52958654; called by muse, mutect2, varscan2
- AMIGO3 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57537734; called by muse, mutect2
- AP3M2 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV51528419; called by muse, mutect2
- APLP2 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53840442; called by muse, mutect2, varscan2
- APOB | c.10474A>T p.I3492F | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV51932598; called by muse, mutect2, varscan2
- ARHGAP5 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV61535138; called by muse, mutect2
- ATM | c.8650G>C p.E2884Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV53739484; called by muse, mutect2, varscan2
- ATP2B2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59494471; called by muse, mutect2, varscan2
- ATP2B4 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV58176784; called by muse, mutect2
- BAHCC1 | c.5959C>G p.Q1987E | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.968); catalogued as COSV57025571; called by muse, mutect2, varscan2
- BANK1 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV59841769, COSV59848750; called by muse, mutect2
- BUD13 | c.534G>T p.R178S | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV52767972; called by muse, mutect2, varscan2
- BUD13 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV52767984; called by muse, mutect2, varscan2
- C20orf194 | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 46/378 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.352); catalogued as COSV52694789; called by muse, mutect2, varscan2
- C8A | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63483756; called by muse, mutect2
- CALCR | c.959C>A p.P320H (on ENST00000649521 / NM_001164737.2; = p.P304H on NM_001742.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100810544; called by muse, mutect2
- CAMTA2 | c.2428G>C p.E810Q | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52777061, COSV52777539; called by muse, mutect2, varscan2
- CDON | c.3262C>T p.H1088Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs767733147, COSV54997196; called by muse, mutect2, varscan2
- CHRM4 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as rs777815412, COSV63126373; called by muse, mutect2, varscan2
- CHRNB4 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55715717; called by muse, mutect2, varscan2
- CHST15 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60561613; called by muse, mutect2, varscan2
- CLEC9A | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV63349326, COSV63350044; called by muse, mutect2, varscan2
- CLSTN3 | c.1693A>T p.M565L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56935713; called by muse, mutect2, varscan2
- CSMD3 | c.9229A>T p.T3077S (on ENST00000297405 / NM_001363185.1; = p.T2908S on NM_052900.3) | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52159165; called by muse, mutect2
- CTNNB1 | c.2048T>A p.F683Y | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV62697852; called by muse, mutect2
- CTRB2 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57315538; called by muse, mutect2
- CUL3 | c.989C>A p.S330Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV52363928; called by muse, mutect2
- CYP4A11 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV60223142; called by muse, mutect2
- DACT1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755263046, COSV60019157; called by muse, mutect2
- DAPK1 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV104419151, COSV63786777; called by muse, mutect2, varscan2
- DCAF12L1 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV64421602; called by muse, mutect2, varscan2
- DDHD1 | c.1943C>T p.S648F (on ENST00000323669; = p.S845F on NM_030637.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60358769; called by muse, mutect2, varscan2
- DNAJC16 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV65448445; called by muse, mutect2, varscan2
- DROSHA | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1184774985, COSV60775017; called by muse, mutect2
- EGFR | c.2507G>A p.R836H | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146121458, COSV51793030; called by muse, mutect2
- EXOC3L1 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV52045962; called by muse, mutect2, varscan2
- FANCD2 | c.1306C>A p.L436M | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373898927, COSV55039136, COSV99812300; called by muse, mutect2
- FBN3 | c.6575G>C p.C2192S | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54458817; called by muse, mutect2
- FBXO39 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.558); catalogued as COSV58621619; called by muse, mutect2, varscan2
- FRMD3 | c.1040A>T p.K347M | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV58459992; called by muse, mutect2, varscan2
- FRMD4A | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV52720563; called by muse, varscan2
- FRMD4A | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52720590; called by muse, varscan2
- FSCN2 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.982); catalogued as rs956779574, COSV58367386; called by muse, mutect2, varscan2
- GABRB2 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV50908449; called by muse, mutect2, varscan2
- GIGYF1 | c.2113C>G p.R705G | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs754888392, COSV51940437, COSV51941059; called by muse, mutect2
- GLP2R | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV52324224; called by muse, mutect2, varscan2
- H3-3B | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.324); catalogued as COSV54665909; called by muse, mutect2, varscan2
- HK2 | c.2428G>C p.E810Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.111); catalogued as COSV51874760, COSV99308910; called by muse, mutect2, varscan2
- JCHAIN | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV54658618, COSV54658831; called by muse, mutect2
- KIF16B | c.3003G>C p.Q1001H | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.995); catalogued as COSV61705151; called by muse, mutect2
- KIFC2 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100023829, COSV56760859; called by muse, mutect2, varscan2
- KRTAP10-11 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 32/453 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV58177656; called by muse, mutect2
- LONRF2 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66539461, COSV66542555; called by muse, mutect2, varscan2
- LRBA | c.3974C>T p.S1325L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV63953694; called by muse, mutect2, varscan2
- LRG1 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1448853437, COSV56703414; called by muse, mutect2
- LRP1 | c.8218G>C p.E2740Q | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.158); catalogued as COSV54508822; called by muse, mutect2
- LRP2 | c.8548G>C p.D2850H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55561661; called by muse, mutect2
- LRRC66 | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58632857, COSV58637358; called by muse, mutect2
- LRRIQ1 | c.4324G>C p.D1442H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV67829543; called by muse, mutect2, varscan2
- LY6G5B | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV65497811; called by muse, mutect2, varscan2
- MAGI1 | c.2786G>A p.R929H (on ENST00000402939 / NM_001033057.2; = p.R957H on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.355); catalogued as rs368569997; called by muse, mutect2, varscan2
- MAML2 | c.2259G>C p.L753F | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as COSV73263240, COSV73263930; called by muse, mutect2, varscan2
- MRM2 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54248003; called by muse, mutect2, varscan2
- MSLN | c.1234C>G p.P412A | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.424); catalogued as COSV53501416, COSV53506382; called by muse, mutect2, varscan2
- MXRA5 | c.5210C>G p.T1737S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99479274; called by muse, mutect2
- MYCBP2 | c.8434C>G p.L2812V (on ENST00000357337; = p.L2850V on NM_015057.5) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1440967844, COSV62016152; called by muse, mutect2
- MYO16 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51795848; called by muse, mutect2
- NACA2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); catalogued as rs750416162, COSV71713119; called by muse, mutect2, varscan2
- NAE1 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV51975749; called by muse, mutect2, varscan2
- NINL | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs779687148, COSV54001337; called by muse, mutect2, varscan2
- NLRC4 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61592302, COSV61593783; called by muse, mutect2, varscan2
- NTS | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55455913; called by muse, mutect2
- OPN1LW | c.744G>A p.A248= | Splice Region (SNP) | VAF 8/76 reads (11%) | catalogued as rs139583770, COSV64049361; called by muse, mutect2, varscan2
- OR10J1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71128701; called by muse, mutect2
- PARD3 | c.3541C>G p.Q1181E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV61054262; called by muse, mutect2, varscan2
- PCDHA1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs782599305, COSV65373425; called by muse, mutect2
- PFN1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV52590684, COSV99337334; called by muse, varscan2
- PIWIL1 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1409689482, COSV55346048; called by muse, mutect2, varscan2
- PLIN2 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV52803052; called by muse, mutect2
- PLXNB2 | c.3486G>C p.Q1162H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV100833896, COSV63781165; called by muse, mutect2, varscan2
- PRR23B | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV61493538; called by muse, mutect2, varscan2
- PUM1 | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | catalogued as COSV57081142; called by muse, mutect2, varscan2
- ROBO2 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453631792, COSV59899710; called by muse, mutect2
- RTL8A | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66188537; called by muse, mutect2, varscan2
- SGO2 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV63415989; called by muse, mutect2
- SHROOM1 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV60581003; called by muse, mutect2, varscan2
- SMCO1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV58837376; called by muse, mutect2, varscan2
- SPTB | c.4291C>G p.R1431G | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV67630957, COSV67631190; called by muse, mutect2
- STAT2 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.915); catalogued as COSV58475076; called by muse, mutect2
- STMN4 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56108746; called by muse, mutect2, varscan2
- SZT2 | c.5780G>A p.R1927H (on ENST00000634258 / NM_001365999.1; = p.R1870H on NM_015284.4) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs375009349; called by muse, mutect2
- TAC3 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV55648083; called by muse, mutect2, varscan2
- TAS2R31 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as COSV66830214; called by muse, mutect2
- TBX19 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV63197264; called by muse, mutect2
- TCHH | c.5539G>A p.A1847T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs1248281661, COSV64274248; called by muse, mutect2
- TCHH | c.5033A>C p.E1678A | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV64274252; called by muse, mutect2
- TCHH | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | PolyPhen benign (0.007); catalogued as COSV64274258; called by muse, varscan2
- TENM2 | c.4838A>G p.Y1613C (on ENST00000518659 / NM_001122679.2; = p.Y1374C on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV69128185; called by muse, mutect2
- THRAP3 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as rs1337224077; called by muse, mutect2
- TMC6 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs750652637, COSV59808694; called by muse, mutect2
- TNFRSF9 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as rs555723076, COSV66348671; called by muse, mutect2, varscan2
- TOGARAM2 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs150801790, COSV65420236; called by muse, mutect2, varscan2
- TOR1AIP1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs756916997, COSV54869213; called by muse, mutect2
- TRPM3 | c.3457A>G p.I1153V (on ENST00000357533 / NM_001366142.2; = p.I1008V on NM_020952.6) | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV62584612; called by muse, mutect2
- TYK2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777227495, COSV53386549; called by muse, mutect2, varscan2
- VPS13B | c.7942G>A p.D2648N | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62139320; called by muse, mutect2, varscan2
- VPS13D | c.7361C>T p.S2454F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV50633926; called by muse, mutect2
- VWA3B | c.1431G>C p.E477D | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV68242387; called by muse, mutect2, varscan2
- WDR70 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1474479310, COSV54271243; called by muse, mutect2
- WFDC3 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV54784884; called by muse, mutect2
- XIRP1 | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV61138050; called by muse, mutect2, varscan2
- XIRP2 | c.3472G>C p.E1158Q (on ENST00000628543; = p.E1333Q on NM_152381.6) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54695174; called by muse, mutect2, varscan2
- XYLT2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.482); catalogued as COSV50017521; called by muse, mutect2, varscan2
- ZBED9 | c.449T>A p.V150D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV71729348; called by muse, mutect2, varscan2
- ZNF329 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748652358, COSV63772212; called by muse, mutect2
- ZNF438 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1173884587, COSV59191788, COSV59194159; called by muse, mutect2
- ZNF524 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV55607590; called by muse, mutect2, varscan2
- ZNF551 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.371); catalogued as COSV56592367; called by muse, mutect2
- ZNF846 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs375362777, COSV67412034; called by muse, mutect2, varscan2
- ANAPC2 | c.1884G>C p.Q628H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- ARAP3 | c.1988C>G p.S663* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- CCDC88A | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2
- CDON | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.615); called by muse, mutect2
- CXCR5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2
- FAM184A | c.2302-2A>G p.X768_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- FLG2 | c.4532C>G p.S1511* | Nonsense Mutation (SNP) | VAF 87/474 reads (18%) | called by muse, mutect2
- HCAR1 | c.34dup p.D12Gfs*50 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by pindel, varscan2
- KLHL4 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2
- MRC1 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYO9A | c.5686G>C p.A1896P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2
- NUTM2G | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PAX9 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- PPIP5K2 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SINHCAF | c.306G>C p.R102S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- SLC2A3 | c.96T>A p.N32K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SMAD7 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SMARCAD1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- TAAR8 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- YWHAZ | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- ZFP36L1 | c.125dup p.T43Hfs*32 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- ZNF37A | c.675C>G p.S225R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2
- ADCY7 | c.1641C>T p.D547= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs779459779, COSV54265946; called by muse, mutect2
- ARHGAP33 | c.3024C>T p.Y1008= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs765929698, COSV50122033; called by muse, mutect2, varscan2
- BLOC1S5 | c.237G>A p.L79= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV55241256; called by muse, mutect2, varscan2
- C6orf15 | c.189C>T p.P63= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as rs375274768; called by muse, mutect2, varscan2
- CAND2 | c.2952A>G p.P984= (on ENST00000456430 / NM_001162499.2; = p.P891= on NM_012298.3) | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs755509819, COSV55989085; called by muse, mutect2, varscan2
- CCDC80 | c.306G>A p.V102= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV52816326; called by muse, mutect2, varscan2
- CCDC9 | c.975G>A p.P325= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as rs746876329, COSV55720428; called by muse, mutect2
- CNTNAP5 | c.3780G>C p.R1260= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV70482797; called by muse, mutect2
- CPA6 | c.1284C>A p.I428= | Silent (SNP) | VAF 14/203 reads (7%) | catalogued as COSV52727219; called by muse, mutect2
- CTCFL | c.564G>A p.K188= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV54773342; called by muse, mutect2, varscan2
- DENND2B | c.2697C>G p.V899= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV58203003; called by muse, mutect2
- DENND3 | c.699C>T p.F233= | Silent (SNP) | VAF 35/208 reads (17%) | catalogued as COSV52802154; called by muse, mutect2, varscan2
- DPEP3 | c.1314C>T p.L438= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs371421204, COSV99262575; called by muse, mutect2, varscan2
- FAT4 | c.3009C>T p.V1003= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV67884625; called by muse, mutect2
- FCGR2B | c.324C>T p.S108= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as rs528404100; called by muse, mutect2
- FOXQ1 | c.492C>A p.R164= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs1390746223, COSV57258777; called by muse, mutect2
- GEMIN4 | c.1821C>G p.L607= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV56745607; called by muse, mutect2, varscan2
- HDLBP | c.3735C>T p.S1245= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV51470944; called by muse, mutect2, varscan2
- KCNG2 | c.1008C>T p.F336= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1320159555; called by muse, mutect2
- KLB | c.2478C>T p.F826= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV57301298; called by muse, mutect2, varscan2
- KLHDC8B | c.453T>C p.R151= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV60411703; called by muse, mutect2
- LARS1 | c.2295C>A p.L765= (on ENST00000394434 / NM_020117.11; = p.L738= on NM_016460.3) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV50974609; called by muse, mutect2, varscan2
- LIPE | c.2184G>A p.G728= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV54922386; called by muse, mutect2, varscan2
- LRRC66 | c.1359G>A p.E453= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV58632386; called by muse, mutect2
- LRRIQ4 | c.588C>T p.D196= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs1167416990, COSV61619016; called by muse, mutect2
- LYST | c.11358G>A p.L3786= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV67706253; called by muse, mutect2
- MTNR1B | c.178C>T p.L60= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs767570148, COSV57066238; called by muse, mutect2, varscan2
- MYORG | c.66A>G p.A22= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- PCDHA9 | c.2052G>T p.V684= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV65325662; called by muse, mutect2, varscan2
- PEG3 | c.319C>A p.R107= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as COSV55631206, COSV99687501; called by muse, mutect2
- PLAG1 | c.321G>A p.L107= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- PPARD | c.210C>G p.L70= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV61099485; called by muse, mutect2, varscan2
- PPARG | c.783G>C p.A261= (on ENST00000287820 / NM_015869.5; = p.A231= on NM_005037.7) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs770030248, COSV55142021; called by muse, mutect2, varscan2
- PRAMEF7 | c.1002C>T p.F334= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs144939857; called by muse, mutect2, varscan2
- PTPN21 | c.3519C>G p.L1173= | Silent (SNP) | VAF 40/295 reads (14%) | catalogued as COSV60847612; called by muse, mutect2, varscan2
- PTPRB | c.702T>C p.T234= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV57698608; called by muse, mutect2
- RPS6KC1 | c.2784C>T p.R928= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs367715701; called by muse, mutect2
- SIGLEC9 | c.312G>A p.L104= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV51583762; called by muse, mutect2, varscan2
- SRGAP1 | c.1536C>G p.V512= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV61896899; called by muse, mutect2, varscan2
- SULT1C3 | c.914G>A p.*305= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1311929618, COSV100227307; called by muse, mutect2
- TCP11 | c.702C>G p.L234= (on ENST00000512012; = p.L172= on NM_018679.5) | Silent (SNP) | VAF 71/477 reads (15%) | catalogued as rs778994774, COSV55133377; called by muse, mutect2, varscan2
- TMEM106C | c.609C>T p.F203= | Silent (SNP) | VAF 48/276 reads (17%) | catalogued as COSV56742680; called by muse, mutect2, varscan2
- TMEM181 | c.1092C>T p.F364= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV65562935; called by muse, mutect2
- TRIB2 | c.528C>T p.L176= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV50225086, COSV50225124; called by muse, mutect2, varscan2
- TSPAN1 | c.606T>C p.N202= | Silent (SNP) | VAF 22/344 reads (6%) | catalogued as COSV64339708; called by muse, mutect2
- TSPAN14 | c.294C>A p.I98= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs745396195, COSV59367803; called by muse, mutect2, varscan2
- USP11 | c.141C>T p.V47= (on ENST00000218348; = p.V4= on NM_001371072.1) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs377322344; called by muse, mutect2, varscan2
- MIR520H | n.49G>A | RNA (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- OR2U1P | n.276T>C | RNA (SNP) | VAF 34/308 reads (11%) | called by muse, mutect2, varscan2
- PHYHD1 | c.*25C>T | 3'UTR (SNP) | VAF 12/62 reads (19%) | catalogued as rs375648347; called by muse, mutect2, varscan2
- SPTBN1 | c.-1G>C | 5'UTR (SNP) | VAF 76/155 reads (49%) | catalogued as COSV100777192; called by muse, mutect2, varscan2
